Somatic mutation profile of tumor specimen TCGA-DX-A8BZ-01A (aliquot TCGA-DX-A8BZ-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BZ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 79.0 years (28,853 days).
Specimen TCGA-DX-A8BZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5360f0ed-2515-4fca-8368-824d9ab202e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BZ-10A (Blood Derived Normal), aliquot TCGA-DX-A8BZ-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53d9e023-46ee-4ade-82fa-d94e2d4b90b9

The open-access MAF lists 33 somatic variants for this specimen: 19 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 11, Frame Shift Del 2, Splice Region 1, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.1841G>A p.G614D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491664; called by muse, mutect2, varscan2
- ADGRB3 | c.1527A>T p.A509= | Splice Region (SNP) | VAF 14/31 reads (45%) | catalogued as COSV101001968; called by muse, mutect2, varscan2
- ARG2 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99937596; called by muse, mutect2, varscan2
- DNAH8 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368700966; called by muse, mutect2, varscan2
- FAM91A1 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100593798, COSV58240071; called by muse, mutect2
- GBP2 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs140765409; called by muse, mutect2, varscan2
- INHA | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV99217500; called by muse, mutect2, varscan2
- IRAK3 | c.1525T>A p.C509S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99706478; called by muse, mutect2, varscan2
- PARP10 | c.2270G>A p.C757Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100478349; called by muse, mutect2, varscan2
- PHEX | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as COSV101040034; called by muse, mutect2, varscan2
- PHRF1 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV99213467; called by muse, mutect2, varscan2
- RBM10 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV100238302; called by muse, mutect2, varscan2
- RCL1 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100762145; called by mutect2, varscan2
- SERPINA9 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV54074164; called by muse, mutect2, varscan2
- SLC1A6 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1353279163, COSV55673227; called by muse, mutect2, varscan2
- TMC6 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs536179551, COSV59810820; called by muse, mutect2, varscan2
- TTN | c.22441G>A p.V7481M (on ENST00000591111; = p.V6554M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen possibly damaging (0.638); catalogued as rs144032104; ClinVar: uncertain significance / benign; called by muse, mutect2
- GIN1 | c.1162del p.V388Lfs*6 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- KCNT1 | c.78del p.F27Sfs*28 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- F2 | c.834G>T p.G278= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100319699; called by muse, mutect2, varscan2
- FBL | c.270G>A p.P90= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs369326013; called by muse, mutect2
- FLNA | c.5520C>T p.H1840= (on ENST00000369850 / NM_001110556.2; = p.H1832= on NM_001456.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs781795295, COSV61044773; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIP1 | c.1455C>A p.I485= (on ENST00000359742 / NM_001379345.1; = p.I433= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1565745155, COSV99671008; called by muse, mutect2, varscan2
- MAOA | c.444T>C p.H148= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100109026; called by muse, mutect2, varscan2
- MMAB | c.111T>G p.P37= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99904680; called by muse, mutect2, varscan2
- MSH4 | c.670T>C p.L224= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99592544; called by muse, mutect2, varscan2
- PRDM16 | c.3222G>T p.S1074= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV99578810; called by muse, mutect2, varscan2
- RGL2 | c.1083C>T p.S361= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV101004842; called by muse, mutect2, varscan2
- SPTA1 | c.6924C>A p.P2308= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100935580; called by muse, mutect2, varscan2
- ZAP70 | c.360C>T p.D120= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs768492740, COSV53854066; ClinVar: likely benign; called by muse, varscan2
- AL133467.6 | chr14:95668445 G>A | 5'Flank (SNP) | VAF 9/16 reads (56%) | catalogued as rs556889158; called by muse, varscan2
- KIR3DX1 | n.864C>T | RNA (SNP) | VAF 20/43 reads (47%) | catalogued as rs760842823, COSV55597926; called by muse, mutect2, varscan2
- NDUFB2 | c.98+1414G>T | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99199995; called by muse, mutect2, varscan2
